Somatic mutation profile of tumor specimen TCGA-A5-A0R9-01A (aliquot TCGA-A5-A0R9-01A-11D-A10B-09) from TCGA case TCGA-A5-A0R9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 52.0 years (18,982 days).
Specimen TCGA-A5-A0R9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ed7db28-ccb4-4f19-aa53-7257ae5184de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0R9-10A (Blood Derived Normal), aliquot TCGA-A5-A0R9-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eb8f522-4e6f-456b-a8e2-7ebc6f293d71

The open-access MAF lists 49 somatic variants for this specimen: 42 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 35, Silent 7, Frame Shift Del 3, Splice Site 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- DDX3X | c.1700C>T p.P567L (on ENST00000399959; = p.P568L on NM_001356.5) | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519430, CM158051, COSV67863241; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1348_1350del p.H450del (on ENST00000521381 / NM_181523.3; = p.H180del on NM_181504.4) | In Frame Del (DEL) | VAF 34/100 reads (34%) | hotspot (GDC flag); catalogued as COSV57139967; called by mutect2, pindel, varscan2
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 16/37 reads (43%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781800676, CM074052, COSV52272085; called by muse, mutect2, varscan2
- BRCA2 | c.2116G>T p.A706S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.209); catalogued as COSV101204511; called by muse, mutect2
- CTCF | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50462744; called by muse, mutect2, varscan2
- DNMT1 | c.4456G>A p.D1486N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV61583967; called by muse, varscan2
- DOCK3 | c.4364G>A p.R1455Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.83); catalogued as rs940869483, COSV56517018; called by muse, mutect2, varscan2
- DTX1 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57496576, COSV57501591; called by muse, mutect2, varscan2
- DUSP16 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs762231755, COSV53809786; called by muse, mutect2
- FAAH2 | c.1342G>C p.V448L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV66512003; called by muse, mutect2, varscan2
- GNAI2 | c.724A>C p.N242H | Missense Mutation (SNP) | VAF 116/235 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56495878; called by muse, mutect2, varscan2
- HEATR1 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.438); catalogued as COSV63983059; called by muse, mutect2
- HGFAC | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs577434025, COSV66977323; called by muse, mutect2, varscan2
- HIBADH | c.613G>C p.G205R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55317128; called by muse, mutect2, varscan2
- IRX1 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.32); catalogued as rs1256765708, COSV57362510; called by muse, mutect2, varscan2
- KIAA0408 | c.1499A>G p.H500R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.153); catalogued as COSV64108753; called by muse, mutect2, varscan2
- LAMB2 | c.4736A>G p.D1579G | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV59738099; called by muse, mutect2, varscan2
- MYO15A | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs990963529, COSV52764171, COSV52765249; called by muse, mutect2
- NDRG4 | c.88C>T p.R30C (on ENST00000570248 / NM_001378344.1; = p.R62C on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs202237732; called by muse, mutect2, varscan2
- PCDHA2 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65366515, COSV65367971; called by muse, mutect2, varscan2
- PKD2L1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs1404081116, COSV58396568; called by muse, mutect2, varscan2
- PLXNA4 | c.1742del p.T581Sfs*64 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as COSV58160719; called by pindel, varscan2
- PRAMEF1 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.843); catalogued as COSV60018738; called by muse, varscan2
- PRAMEF2 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.53); catalogued as rs1170412347, COSV53579368; called by muse, mutect2, varscan2
- PTEN | c.775del p.H259Tfs*7 | Frame Shift Del (DEL) | VAF 34/58 reads (59%) | catalogued as COSV64289147; called by mutect2, pindel, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs146650273; called by pindel, varscan2
- SCN11A | c.2398C>A p.L800I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56578558; called by muse, mutect2, varscan2
- SGSM2 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370623935; called by muse, mutect2, varscan2
- SIPA1L3 | c.3022G>A p.V1008M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376550640; called by muse, mutect2, varscan2
- SLCO1B3 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as COSV53946689; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | PolyPhen benign (0); catalogued as rs756951441, COSV56572706; called by muse, mutect2, varscan2
- TSC2 | c.4313G>A p.R1438Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs45448791, CM041089, COSV51925788; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- VWA8 | c.2120T>C p.I707T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV55705539; called by muse, mutect2, varscan2
- XYLT1 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374020411, COSV54479975; called by muse, mutect2, varscan2
- ZEB2 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs730881174, COSV57955413, COSV57957804; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFHX4 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV51486660; called by muse, mutect2
- ZNF334 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1555856152, COSV61619346; called by muse, mutect2, varscan2
- CCDC137 | c.522dup p.V175Sfs*26 | Frame Shift Ins (INS) | VAF 83/239 reads (35%) | called by mutect2, pindel, varscan2
- DMAP1 | c.1344+2dup p.X448_splice | Splice Site (INS) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- SCN2A | c.5945A>G p.E1982G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by mutect2, varscan2
- GYG1 | c.987G>A p.Q329= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV56051216; called by muse, mutect2, varscan2
- PCSK5 | c.738C>T p.D246= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs150358970, COSV65091616; called by muse, mutect2, varscan2
- PDE11A | c.1506C>T p.D502= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV53708902; called by muse, mutect2, varscan2
- PRRT3 | c.2676C>T p.P892= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs767304544, COSV55978627; called by muse, mutect2, varscan2
- TMEM74 | c.720G>A p.T240= | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as rs768735594, COSV52462569; called by muse, mutect2, varscan2
- TTN | c.852G>A p.S284= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs768340304, COSV60354589; called by muse, mutect2, varscan2
- ZNF628 | c.1932C>T p.H644= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs771060228, COSV52702457; called by muse, mutect2
